Somatic mutation profile of tumor specimen TCGA-EM-A3AJ-01A (aliquot TCGA-EM-A3AJ-01A-11D-A202-08) from TCGA case TCGA-EM-A3AJ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 39.4 years (14,399 days).
Specimen TCGA-EM-A3AJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ee6b05c-13b2-4740-bb8a-591580a26071.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3AJ-10A (Blood Derived Normal), aliquot TCGA-EM-A3AJ-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/356f2d46-b472-43a1-9ece-157ac77779d5

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.1190G>A p.W397* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV51399406, COSV99273440; called by muse, mutect2, varscan2
- CCDC170 | c.1994T>G p.V665G | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV53336983; called by muse, mutect2, varscan2
- CNTLN | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as COSV52067633; called by muse, mutect2, varscan2
- TRAFD1 | c.1384T>G p.Y462D | Missense Mutation (SNP) | VAF 17/293 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as COSV57503510; called by muse, mutect2
- NUAK1 | c.1695C>T p.Y565= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs142540856; called by muse, mutect2, varscan2
